Somatic mutation profile of tumor specimen TCGA-XU-A92O-01A (aliquot TCGA-XU-A92O-01A-11D-A423-09) from TCGA case TCGA-XU-A92O, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type A, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 63.5 years (23,186 days).
Specimen TCGA-XU-A92O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18ae1d01-e96a-4884-86ca-af922642e63b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A92O-10A (Blood Derived Normal), aliquot TCGA-XU-A92O-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b272fe1-c566-4bc9-bd51-1214ba041bac

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 19, Silent 7, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 177/627 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 31/99 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ALMS1 | c.6931G>A p.V2311I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs750322171; called by muse, mutect2, varscan2
- AMH | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs751597455; called by muse, varscan2
- CTNND2 | c.2371G>T p.D791Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58862960; called by muse, mutect2, varscan2
- F8 | c.2598G>T p.M866I | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100811453; called by muse, mutect2, varscan2
- IGSF1 | c.3103C>T p.R1035C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs750269789, COSV100811831; called by muse, mutect2, varscan2
- OR14A16 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs747877443, COSV100713872, COSV62926005; called by muse, mutect2, varscan2
- PPP4R4 | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs779892770, COSV58552935; called by muse, mutect2, varscan2
- PTDSS2 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs191633129; called by muse, mutect2, varscan2
- SLC39A13 | c.589T>C p.C197R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs779407804; called by muse, mutect2, varscan2
- SPTA1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs370498187; called by muse, mutect2, varscan2
- BMPR1B | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD2 | c.421T>A p.C141S | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CLIP1 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MEOX1 | c.656T>C p.F219S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO9B | c.2434A>G p.T812A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- TBK1 | c.357G>A p.V119= | Splice Region (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- TRIO | c.3988C>A p.P1330T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF519 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- EPPK1 | c.5262G>T p.L1754= | Silent (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- FRA10AC1 | c.945A>G p.L315= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as rs995274223; called by muse, mutect2, varscan2
- KIRREL3 | c.1101C>A p.V367= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- PDE4DIP | c.7035C>T p.A2345= | Silent (SNP) | VAF 53/148 reads (36%) | called by muse, mutect2, varscan2
- RYR1 | c.6687G>C p.V2229= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- SDK2 | c.3309G>A p.V1103= | Silent (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- TPTE | c.1404C>T p.D468= (on ENST00000618007 / NM_199261.4; = p.D450= on NM_199259.4) | Silent (SNP) | VAF 27/162 reads (17%) | catalogued as rs141834444; called by muse, mutect2, varscan2
